TCGA case TCGA-42-2588 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/654d02ab-05b4-4863-99d9-04d087ff91b4

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Dead; Days to death: 880 days (2.4 years).

Diagnoses (3)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 61.3 years (22,377 days); Year of diagnosis: 2009; Method of diagnosis: Cytology; FIGO stage: Stage IV; Tumor grade: G3; Prior treatment: No; Residual disease: R2.
   Pathology details: Lymphatic invasion present: Yes; Residual tumor measurement: >20 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 22 days; Days to treatment end: 90 days; Number of cycles: 4; Treatment dose: 2,169 mg; Prescribed dose: 558; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 48 days; Days to treatment end: 104 days; Number of cycles: 3; Treatment dose: 948 mg; Prescribed dose: 137; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 161 days; Days to treatment end: 258 days; Number of cycles: 4; Treatment dose: 2,360 mg; Prescribed dose: 590; Prescribed dose units: mg; Route of administration: Intraperitoneal.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Progressive Disease; Days to treatment start: 161 days; Days to treatment end: 258 days; Number of cycles: 4; Treatment dose: 1,146 mg; Prescribed dose: 97; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 315 days; Days to treatment end: 399 days (1.1 years); Number of cycles: 4; Treatment dose: 248 mg; Prescribed dose: 60; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 343 days; Days to treatment end: 399 days (1.1 years); Number of cycles: 3; Treatment dose: 2,323 mg; Prescribed dose: 747; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Progressive Disease; Days to treatment start: 427 days (1.2 years); Days to treatment end: 427 days (1.2 years); Number of cycles: 1; Treatment dose: 72 mg; Prescribed dose: 72; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Progressive Disease; Days to treatment start: 427 days (1.2 years); Days to treatment end: 602 days (1.6 years); Number of cycles: 8; Treatment dose: 10,302 mg; Prescribed dose: 621; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 455 days (1.2 years); Days to treatment end: 595 days (1.6 years); Number of cycles: 7; Treatment dose: 1,862 mg; Prescribed dose: 266; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Letrozole; Initial disease status: Progressive Disease; Days to treatment start: 687 days (1.9 years); Days to treatment end: 784 days (2.1 years); Treatment dose: 245 mg; Prescribed dose: 2.5; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Megestrol Acetate; Initial disease status: Progressive Disease; Days to treatment start: 687 days (1.9 years); Days to treatment end: 784 days (2.1 years); Number of cycles: 1; Treatment dose: 39,200 mg; Prescribed dose: 400; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Progressive Disease; Days to treatment start: 735 days (2.0 years); Days to treatment end: 819 days (2.2 years); Number of cycles: 4; Treatment dose: 4,881 mg; Prescribed dose: 675; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 744 days (2.0 years); Days to treatment end: 819 days (2.2 years); Number of cycles: 4; Treatment dose: 1,203 mg; Prescribed dose: 300; Prescribed dose units: mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 61.6 years (22,489 days); Days to diagnosis: 112 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 141 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.
3. Progression of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 62.0 years (22,644 days); Days to diagnosis: 267 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.

Follow-up (6 entries)
- Day 112 (post initial treatment): Progression or recurrence: Yes; Days to progression: 112 days.
- Day 267 (post initial treatment): Progression or recurrence: Yes; Days to progression: 267 days.
- Days to follow up: 287 days; Disease response: With Tumor.
- Days to follow up: 880 days (2.4 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Distant; Timepoint: Post Initial Treatment.
- ECOG performance status: 2; Timepoint: Preoperative.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-42-2588-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.9; Intermediate dimension: 0.7; Shortest dimension: 0.4.
  Slide TCGA-42-2588-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 80; Percent normal cells: 15; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-42-2588-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-42-2588-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-42-2588-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Cytology (e.g. Peritoneal or pleural fluid); Lymphovascular invasion indicator: Yes.
- Drug treatment 1, Route of administrations: Route of administration: IP.
- Drug treatment 2: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 2, Route of administrations: Route of administration: IV.
- Drug treatment 5: Regimen number: 06.
- Drug treatment 6: Regimen number: 04.
- Drug treatment 8: Regimen number: 03; Pharmaceutical therapy drug name: Doxil.
- Drug treatment 10: Regimen number: 03; Pharmaceutical therapy drug name: Avastin.
- Drug treatment 11: Regimen number: 05.
- Drug treatment 11, Route of administrations: Route of administration: PO.
- Drug treatment 13: Regimen number: 05; Pharmaceutical therapy drug name: Femara.

GDC annotations on this case (curator notes; quoted as recorded):
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-42-2588-01A-01R-1048-01: Pairwise comparisons of expression results between platforms HT_HG-U133A and AgilentG4502A_07 suggests that results from this aliquot were from a different patient and therefore these data have been removed.
- Pathology outside specification: Pathology Results off Spec.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 880 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 880 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 112 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-42-2588-01A-01D-1043-01): tumor purity 0.57, ploidy 2.25, whole-genome doublings 0.
